Somatic mutation profile of tumor specimen TCGA-67-3774-01A (aliquot TCGA-67-3774-01A-01W-0928-08) from TCGA case TCGA-67-3774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.1 years (26,704 days).
Specimen TCGA-67-3774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb4ca6a-dce8-474b-995e-0332b3cf9876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3774-10A (Blood Derived Normal), aliquot TCGA-67-3774-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2c68d77-2501-4a35-9654-9a96e8cea210

The open-access MAF lists 111 somatic variants for this specimen: 79 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 28, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 3, RNA 2, Splice Region 1, Intron 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 37/94 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA8 | c.3518T>C p.F1173S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52202679; called by muse, mutect2, varscan2
- ACTRT1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 165/1043 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV64418931, COSV64419524; called by muse, mutect2, varscan2
- ADCY8 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV53910375; called by muse, mutect2, varscan2
- ADGRV1 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.2); catalogued as COSV67986493; called by muse, mutect2, varscan2
- AHNAK | c.8486A>T p.H2829L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV57215609; called by muse, varscan2
- APOBEC3G | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV68470349; called by muse, mutect2, varscan2
- CACNA1D | c.4445T>C p.L1482S (on ENST00000350061 / NM_001128840.3; = p.L1502S on NM_000720.4) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449140; called by mutect2, varscan2
- CACNA2D3 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.35); catalogued as COSV55544330; called by muse, mutect2, varscan2
- CAPN5 | c.694G>A p.G232S (on ENST00000456580; = p.G192S on NM_004055.5) | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53688330; called by muse, mutect2, varscan2
- CAPN5 | c.1233G>C p.Q411H (on ENST00000456580; = p.Q371H on NM_004055.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV53688372; called by muse, mutect2
- CASR | c.2077C>A p.L693I (on ENST00000490131; = p.L770I on NM_000388.4) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.146); catalogued as COSV56138101; called by muse, mutect2, varscan2
- CCDC27 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV53900680; called by muse, mutect2, varscan2
- CCDC73 | c.3196dup p.R1066Kfs*17 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs781654336; called by pindel, varscan2
- CEP85 | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775213951, COSV53329801; called by muse, mutect2, varscan2
- CHST1 | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57323868; called by muse, mutect2, varscan2
- DAW1 | c.42A>T p.G14= | Splice Region (SNP) | VAF 18/93 reads (19%) | catalogued as COSV59365900; called by muse, mutect2, varscan2
- DCAF4L2 | c.414G>T p.L138F | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.862); catalogued as COSV60479278; called by muse, mutect2, varscan2
- DSCAM | c.3803G>A p.G1268E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68027878; called by muse, mutect2, varscan2
- EFHB | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55547798, COSV55548892; called by muse, mutect2, varscan2
- ELMO1 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV60306491; called by muse, mutect2, varscan2
- ENTPD4 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 194/843 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62269200; called by muse, mutect2, varscan2
- ERMAP | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771020983, COSV60273608; called by muse, mutect2, varscan2
- EXOG | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55063514; called by muse, mutect2, varscan2
- F8 | c.4856C>A p.S1619Y | Missense Mutation (SNP) | VAF 233/924 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV64274144; called by muse, mutect2, varscan2
- FAM83B | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775965658, COSV60922593; called by muse, mutect2, varscan2
- FAM83G | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373051640; called by mutect2, varscan2
- GAD2 | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV52158703; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GRB2 | c.158T>G p.I53R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57304985; called by muse, mutect2, varscan2
- HOXB1 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV99495359; called by muse, varscan2
- HOXB1 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99495363; called by muse, varscan2
- IFT81 | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs774415653, COSV54363028; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as COSV56266184; called by muse, mutect2, varscan2
- ITGAM | c.1898C>T p.A633V (on ENST00000648685 / NM_001145808.2; = p.A632V on NM_000632.4) | Missense Mutation (SNP) | VAF 48/1246 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs1164567661, COSV54937723; called by muse, mutect2
- ITIH6 | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV54489750; called by muse, mutect2, varscan2
- KEAP1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412883238, COSV50283235, COSV50291239; called by muse, mutect2
- KIAA0232 | c.3140C>G p.P1047R | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as rs1168252443, COSV56925774; called by muse, mutect2, varscan2
- KLK3 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as rs773127519, COSV58100763; called by muse, mutect2, varscan2
- LILRB1 | c.721C>A p.P241T (on ENST00000427581; = p.P205T on NM_006669.6) | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV61116765, COSV61118652; called by muse, varscan2
- MAP3K11 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58419909; called by muse, mutect2, varscan2
- ME1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV63839643; called by muse, mutect2, varscan2
- MED13L | c.4547C>G p.T1516S | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.437); catalogued as rs1298577093, COSV56121168; called by muse, mutect2, varscan2
- MME | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV64706889, COSV64707797; called by muse, mutect2, varscan2
- NALCN | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.288); catalogued as rs756729162, COSV51939252; called by muse, mutect2, varscan2
- NOTCH1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs779375653, COSV53056338; called by muse, mutect2
- NPFFR2 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 130/534 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58150337, COSV58155063; called by muse, mutect2, varscan2
- OR10J1 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV71128850, COSV71128932; called by muse, mutect2, varscan2
- PARP1 | c.3023A>G p.N1008S | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1219278582, COSV64690731; called by muse, mutect2, varscan2
- PCDH8 | c.2911G>T p.G971W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100131111, COSV58812848; called by muse, mutect2, varscan2
- PCSK7 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58007547; called by muse, mutect2, varscan2
- PDE1C | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58515518, COSV58520064; called by muse, mutect2, varscan2
- PDS5A | c.2601G>A p.M867I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as COSV57826514; called by muse, mutect2, varscan2
- POF1B | c.1220_1223del p.S407Ffs*12 | Frame Shift Del (DEL) | VAF 92/522 reads (18%) | catalogued as rs1444043025; called by mutect2, pindel, varscan2
- PPM1K | c.999C>G p.Y333* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | catalogued as COSV55796092, COSV55796100; called by muse, mutect2, varscan2
- PRAMEF1 | c.892T>A p.L298M | Missense Mutation (SNP) | VAF 131/560 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100179309, COSV60010135; called by muse, mutect2, varscan2
- PZP | c.4321C>A p.Q1441K | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54361964; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 15/116 reads (13%) | catalogued as rs756557178; called by mutect2, varscan2
- RASL11B | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 106/489 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50535222; called by muse, mutect2, varscan2
- ROBO2 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59914086, COSV59919821; called by muse, mutect2, varscan2
- RPS6KA6 | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53120593; called by muse, mutect2, varscan2
- RYR2 | c.7993G>C p.A2665P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100771999, COSV63672383, COSV63688685; called by muse, mutect2
- SIRPG | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53807804; called by muse, mutect2, varscan2
- SLC36A4 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 48/174 reads (28%) | catalogued as COSV58396351; called by muse, mutect2, varscan2
- STBD1 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52953926; called by muse, mutect2, varscan2
- SULT4A1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV50781268; called by muse, mutect2, varscan2
- TLK2 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58300852; called by muse, mutect2, varscan2
- TM7SF2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.515); catalogued as COSV54207701; called by muse, varscan2
- TNFSF13B | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1303186225, COSV65516367; called by muse, mutect2, varscan2
- TNN | c.3303C>G p.D1101E | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53427344; called by muse, mutect2, varscan2
- TRAK1 | c.1604G>T p.S535I (on ENST00000327628 / NM_001349247.2; = p.S477I on NM_014965.5) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58259417; called by muse, mutect2, varscan2
- UGT2B7 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV59443736; called by muse, mutect2, varscan2
- UNC93A | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs1487332415, COSV57808816; called by muse, mutect2, varscan2
- ZNF536 | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62819610; called by muse, mutect2, varscan2
- MTTP | c.2228del p.L743Yfs*5 | Frame Shift Del (DEL) | VAF 42/171 reads (25%) | called by mutect2, pindel, varscan2
- ROCK1 | c.136_156del p.L46_I52del | In Frame Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- SGCD | c.290del p.P97Qfs*15 (on ENST00000435422 / NM_001128209.2; = p.P98Qfs*15 on NM_000337.5) | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel*
- TKT | c.945del p.I315Mfs*56 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ACIN1 | c.2268G>C p.L756= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as COSV52976978; called by muse, mutect2, varscan2
- ALDH1L1 | c.231G>T p.G77= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV56414737; called by muse, mutect2, varscan2
- ANK1 | c.2643T>A p.S881= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV55883225; called by muse, mutect2, varscan2
- ASXL3 | c.3624T>A p.P1208= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV52467698; called by muse, mutect2, varscan2
- CHD6 | c.4161C>A p.P1387= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV64691296; called by muse, mutect2, varscan2
- COL17A1 | c.345C>T p.G115= | Silent (SNP) | VAF 63/295 reads (21%) | catalogued as COSV62227116; called by muse, mutect2, varscan2
- COL4A1 | c.3234T>A p.P1078= | Silent (SNP) | VAF 108/490 reads (22%) | catalogued as COSV65426756; called by muse, mutect2, varscan2
- CSMD1 | c.6390T>C p.H2130= (on ENST00000520002; = p.H2129= on NM_033225.6) | Silent (SNP) | VAF 48/207 reads (23%) | catalogued as COSV59331849; called by muse, mutect2, varscan2
- DSG1 | c.252A>T p.T84= | Silent (SNP) | VAF 67/352 reads (19%) | catalogued as COSV57136075; called by muse, mutect2, varscan2
- HNRNPL | c.1203T>C p.N401= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs1413890278, COSV55493005; called by muse, mutect2, varscan2
- KRTAP10-9 | c.570T>A p.P190= | Silent (SNP) | VAF 83/366 reads (23%) | catalogued as COSV59964791; called by muse, mutect2, varscan2
- MOXD1 | c.1341G>A p.T447= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as rs202102392, COSV60945003; called by muse, mutect2, varscan2
- NGEF | c.228G>A p.K76= | Silent (SNP) | VAF 59/212 reads (28%) | catalogued as rs577781370, COSV50925465, COSV50939069; called by muse, mutect2, varscan2
- OR4K1 | c.675C>A p.V225= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV53460452, COSV53461936; called by muse, mutect2, varscan2
- OR5D14 | c.870G>T p.L290= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV59456604, COSV59458899; called by muse, mutect2, varscan2
- ORC2 | c.282T>G p.V94= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52239217; called by muse, mutect2, varscan2
- PCDH19 | c.393A>T p.A131= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV55264270; called by muse, mutect2, varscan2
- PCDHA13 | c.108C>T p.P36= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as COSV56507728; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.906C>T p.P302= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV59012576, COSV59014069; called by muse, mutect2, varscan2
- PER2 | c.105C>T p.S35= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV54524227; called by muse, mutect2, varscan2
- RASGRF2 | c.1497A>C p.T499= | Silent (SNP) | VAF 73/350 reads (21%) | catalogued as rs753350732, COSV54130983; called by muse, mutect2, varscan2
- SCAI | c.156A>T p.P52= (on ENST00000336505 / NM_001144877.3; = p.P75= on NM_173690.5) | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV60613323; called by muse, mutect2, varscan2
- SLC26A8 | c.2220C>A p.V740= | Silent (SNP) | VAF 112/550 reads (20%) | catalogued as COSV62886061, COSV62886866; called by muse, varscan2
- SPG11 | c.3711C>G p.A1237= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as COSV55995804; called by muse, mutect2, varscan2
- UHRF1BP1 | c.504C>T p.R168= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV51956103; called by muse, mutect2, varscan2
- VPS51 | c.2322G>A p.V774= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs996078943, COSV54207678; called by muse, mutect2
- ZNF43 | c.1557T>C p.F519= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as COSV61684213; called by muse, mutect2, varscan2
- ZNF829 | c.324G>T p.L108= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV66986482; called by muse, mutect2, varscan2
- AC073310.1 | n.368C>A | RNA (SNP) | VAF 127/535 reads (24%) | called by muse, mutect2, varscan2
- AC073310.1 | n.369C>A | RNA (SNP) | VAF 128/537 reads (24%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59941T>A | Intron (SNP) | VAF 38/164 reads (23%) | catalogued as COSV99828009; called by muse, mutect2, varscan2
- PRND | chr20:4732516 A>T | 3'Flank (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
